FM case AD6457 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/c6d9e3d9-c64f-453f-adc5-8c80ce8939f6

Female, 61.6 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the fallopian tube; metastasis biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
